Somatic mutation profile of tumor specimen 7782134d-02db-44ee-adfa-fc1372 (aliquot 7782134d-02db-44ee-adfa-fc1372_D8_1) from CPTAC case 16CO011, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 7782134d-02db-44ee-adfa-fc1372: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c605c399-548b-45e4-bc80-37ace6cd4f6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 894e68d6-bf00-47b5-913c-f1c50f (Blood Derived Normal), aliquot 894e68d6-bf00-47b5-913c-f1c50f_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d31ab090-6aca-4d9d-9385-e2cf837f6a5d

The open-access MAF lists 202 somatic variants for this specimen: 142 protein-altering or splice-affecting, 38 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 38, Nonsense Mutation 12, Intron 10, RNA 6, Splice Site 5, In Frame Del 3, 5'UTR 3, Frame Shift Del 2, 3'UTR 2, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 131/388 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121964980, CM051081; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 56/107 reads (52%) | hotspot (GDC flag); catalogued as COSV50993252; called by muse, mutect2, varscan2
- TP53 | c.393_395del p.N131del | In Frame Del (DEL) | VAF 51/94 reads (54%) | hotspot (GDC flag); catalogued as rs879254214; called by pindel, varscan2
- A2M | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.528); catalogued as rs377153333, COSV59383839; called by muse, mutect2, varscan2
- ABCB9 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs139273443; called by muse, mutect2, varscan2
- AC005833.1 | c.1577C>A p.T526N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0); catalogued as rs768543421; called by muse, mutect2, varscan2
- AGTR1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763952495, COSV62557123; called by muse, mutect2, varscan2
- ANTXRL | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs782424062; called by muse, mutect2, varscan2
- APC | c.3175G>T p.E1059* | Nonsense Mutation (SNP) | VAF 99/318 reads (31%) | catalogued as CM016190, COSV57323783; called by muse, varscan2
- BAG6 | c.2168C>T p.S723F (on ENST00000676571; = p.S676F on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs770546772; called by muse, mutect2, varscan2
- BBX | c.1573A>C p.K525Q | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs761236015; called by muse, mutect2
- BTD | c.1447G>C p.G483R | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV57728568; called by muse, mutect2
- CHD5 | c.5746G>A p.A1916T | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs759789009; called by muse, mutect2, varscan2
- CPS1 | c.3500C>A p.T1167K | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM120164; called by muse, mutect2, varscan2
- CSMD1 | c.9615A>G p.I3205M (on ENST00000520002; = p.I3204M on NM_033225.6) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs767533055; called by muse, mutect2, varscan2
- CTNND1 | c.2233G>T p.E745* (on ENST00000399050 / NM_001085458.2; = p.E739* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV62382083; called by muse, mutect2, varscan2
- EPB41L3 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs1237615415, COSV59449013; called by muse, mutect2, varscan2
- EPS15 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV65540577; called by muse, mutect2, varscan2
- EVC | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1295814362; called by muse, mutect2
- FBN2 | c.6086C>T p.P2029L | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52503892; called by muse, mutect2, varscan2
- FGD2 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 50/156 reads (32%) | catalogued as rs376313840; called by muse, mutect2, varscan2
- FRMPD4 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 86/140 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs758319836, COSV66224713; called by muse, varscan2
- GDNF | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753300953, COSV58478254; called by muse, mutect2
- GJA8 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 21/418 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV53789718; called by muse, mutect2
- GRIA3 | c.155G>C p.R52P | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV99991777; called by muse, mutect2
- GSE1 | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779695319; called by muse, mutect2, varscan2
- GTSF1L | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100883953; called by muse, mutect2, varscan2
- HIVEP2 | c.3288G>T p.E1096D | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1194986196; called by muse, mutect2, varscan2
- INSYN2B | c.1464A>C p.E488D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56943589; called by muse, mutect2
- ISLR | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1011177875; called by muse, mutect2, varscan2
- KCNJ6 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55714218; called by muse, mutect2
- LRRC37A | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs1308785193; called by muse, mutect2
- LYRM2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs149413794; called by muse, mutect2, varscan2
- MAGEB10 | c.683A>C p.N228T | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1267768323; called by muse, mutect2
- MARCHF2 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs777630974, COSV53104773; called by muse, mutect2, varscan2
- NALCN | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs749151544; called by muse, varscan2
- OR10J3 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59953818; called by muse, mutect2, varscan2
- OR4X1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.894); catalogued as rs61915300; called by muse, mutect2, varscan2
- OR51B6 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV66513261; called by muse, mutect2, varscan2
- PCDHB7 | c.1198T>G p.F400V | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1554280131, COSV50756008; called by muse, mutect2, varscan2
- PMFBP1 | c.1775T>C p.M592T (on ENST00000537465; = p.M587T on NM_031293.3) | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1159489937; called by muse, mutect2, varscan2
- PRMT2 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1433488950; called by muse, mutect2
- PRRC2C | c.4226C>G p.P1409R (on ENST00000367742; = p.P1407R on NM_015172.4) | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV58901542; called by muse, mutect2
- SCAP | c.3388-1G>C p.X1130_splice | Splice Site (SNP) | VAF 46/168 reads (27%) | catalogued as COSV55545407; called by muse, mutect2, varscan2
- SENP7 | c.299T>C p.M100T | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs750982637; called by muse, mutect2, varscan2
- SLC9A5 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 114/354 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs754013008, COSV100237133; called by muse, mutect2, varscan2
- SPACA1 | c.500C>A p.S167* | Nonsense Mutation (SNP) | VAF 40/108 reads (37%) | catalogued as COSV52760433, COSV99389533; called by muse, mutect2, varscan2
- SPART | c.1559T>G p.L520R | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62084076; called by muse, mutect2
- SPEG | c.3574C>T p.R1192W | Missense Mutation (SNP) | VAF 95/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767242646, COSV56670458; called by muse, mutect2, varscan2
- SSC5D | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs888118455; called by muse, mutect2, varscan2
- STAB2 | c.5953G>A p.E1985K | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as rs372337014; called by muse, mutect2
- STMN4 | c.226G>C p.V76L (on ENST00000265770 / NM_001283054.2; = p.V103L on NM_030795.4) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99740980; called by muse, mutect2, varscan2
- TECTA | c.2336A>G p.K779R | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV50706680; called by muse, mutect2
- TENM3 | c.5265A>T p.Q1755H | Missense Mutation (SNP) | VAF 15/283 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV69300149; called by muse, mutect2
- TMEM79 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs777765530; called by muse, mutect2, varscan2
- TSHZ2 | c.661A>G p.S221G | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100296624; called by muse, mutect2
- TTC12 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs140822336; called by muse, mutect2, varscan2
- USH2A | c.8939A>C p.N2980T | Missense Mutation (SNP) | VAF 116/292 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100228132; called by muse, mutect2, varscan2
- USP26 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192465138, COSV63708068; called by muse, mutect2, varscan2
- USP29 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775387191, COSV54141336, COSV54147725; called by muse, mutect2, varscan2
- VANGL1 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV100048825; called by muse, mutect2
- VPS18 | c.2527C>T p.R843C | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as rs765703231, COSV55029158; called by muse, mutect2
- XIRP2 | c.2496A>C p.E832D (on ENST00000628543; = p.E1007D on NM_152381.6) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54687255; called by muse, mutect2
- ZAN | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.59); PolyPhen benign (0.329); catalogued as rs1465710394, COSV100769699; called by muse, mutect2, varscan2
- ABCA13 | c.9417G>A p.W3139* | Nonsense Mutation (SNP) | VAF 67/337 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.3701G>T p.C1234F | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.2365C>A p.H789N (on ENST00000506720 / NM_001322402.2; = p.H721N on NM_015236.6) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AL445989.1 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ANKS1B | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ASPHD1 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- BRIP1 | c.3500C>T p.A1167V | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- C4orf54 | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- CASZ1 | c.2791C>A p.L931I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC150 | c.924_936+2del | In Frame Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- CELSR2 | c.6608T>C p.I2203T | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2
- CENPL | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- CFAP61 | c.2325C>A p.Y775* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- CNTRL | c.2611_2613del p.E871del | In Frame Del (DEL) | VAF 82/257 reads (32%) | called by pindel, varscan2
- COBL | c.2790G>T p.Q930H | Missense Mutation (SNP) | VAF 61/338 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- COL3A1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CPSF7 | c.1171G>T p.V391F (on ENST00000394888 / NM_001136040.4; = p.V434F on NM_024811.4) | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- CPXCR1 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CSNK1A1L | c.892T>C p.W298R | Missense Mutation (SNP) | VAF 32/582 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2B6 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 28/399 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2
- DEFB127 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTWD2 | c.472G>C p.A158P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- EPHA7 | c.1803A>C p.K601N | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- EPHB4 | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- FAT2 | c.11051T>C p.L3684P | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- FAT2 | c.10691T>C p.L3564P | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCRLA | c.123G>A p.M41I (on ENST00000367959; = p.M24I on NM_032738.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS6 | c.257C>A p.T86K | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- KCNQ2 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KIAA1191 | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.022); called by muse, mutect2
- KIAA1549L | c.1147G>T p.D383Y (on ENST00000321505; = p.D680Y on NM_012194.3) | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- LANCL1 | c.410T>G p.L137R | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRA2 | c.392C>G p.P131R | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRTM4 | c.1593C>A p.D531E | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K8 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 72/228 reads (32%) | called by muse, mutect2
- MCC | c.171-1G>A p.X57_splice | Splice Site (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- MICAL2 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLXIP | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPP7 | c.690+1G>T p.X230_splice | Splice Site (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- MS4A15 | c.310T>G p.F104V (on ENST00000405633 / NM_001098835.2; = p.F11V on NM_152717.3) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYO10 | c.642C>A p.Y214* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- NALCN | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.74); called by muse, mutect2
- NEFH | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- NLRP1 | c.3847C>A p.P1283T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, mutect2
- OR52B6 | c.382_383del p.F128Hfs*12 | Frame Shift Del (DEL) | VAF 64/214 reads (30%) | called by mutect2, pindel, varscan2
- PADI4 | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PALB2 | c.2145T>G p.D715E | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- PCLO | c.14791+6A>T | Splice Region (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- PDHA2 | c.1123G>T p.V375F | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PHLPP2 | c.3847G>T p.V1283L | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLRG1 | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRPH2 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 150/403 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTPN2 | c.261+1G>A p.X87_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- RAP2C | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- RELN | c.8612G>A p.C2871Y | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- RGMB | c.731T>C p.V244A (on ENST00000513185 / NM_001366508.1; = p.V285A on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- RIIAD1 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RLF | c.2902G>T p.A968S | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.053); called by muse, mutect2
- RNF167 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC29A2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 108/332 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, varscan2
- SLC38A9 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMAD3 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- SPAG17 | c.4366A>G p.T1456A | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPARCL1 | c.630A>C p.E210D | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPTA1 | c.6164T>C p.L2055S | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SSH1 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- STEAP3 | c.881G>C p.W294S | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM115 | c.305T>A p.F102Y | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2
- TMEM132C | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM181 | c.928-2A>G p.X310_splice | Splice Site (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- TREH | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPC4 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TRPM8 | c.3224C>A p.S1075* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- USF3 | c.1316C>G p.A439G | Missense Mutation (SNP) | VAF 7/199 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2
- USP24 | c.5214_5217del p.F1739Dfs*3 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- USP28 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX4 | c.9683T>G p.V3228G | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF469 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 57/624 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- ACIN1 | c.1176G>C p.L392= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- AGBL1 | c.1629C>T p.T543= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- CDCA4 | c.207C>A p.I69= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs1436701594; called by muse, mutect2, varscan2
- COQ8A | c.1713C>T p.A571= | Silent (SNP) | VAF 138/369 reads (37%) | catalogued as rs886046069; called by muse, mutect2, varscan2
- DLGAP2 | c.1341C>T p.S447= | Silent (SNP) | VAF 53/163 reads (33%) | catalogued as rs375184000, COSV70099892; called by muse, mutect2, varscan2
- DLK1 | c.933C>T p.G311= | Silent (SNP) | VAF 71/142 reads (50%) | catalogued as rs573553673, COSV57992787; called by muse, mutect2, varscan2
- DMP1 | c.96A>G p.E32= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- FZD10 | c.663C>T p.R221= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV57472529; called by muse, mutect2, varscan2
- GDF2 | c.804C>T p.T268= | Silent (SNP) | VAF 52/371 reads (14%) | called by muse, mutect2, varscan2
- GPRC6A | c.420T>C p.V140= | Silent (SNP) | VAF 20/261 reads (8%) | called by muse, mutect2
- GRM6 | c.369C>T p.G123= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.1680C>T p.S560= (on ENST00000418998 / NM_001377303.1; = p.S470= on NM_015478.7) | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as rs373936477; called by muse, mutect2, varscan2
- LCAT | c.534G>A p.E178= | Silent (SNP) | VAF 162/443 reads (37%) | called by muse, mutect2, varscan2
- LILRB1 | c.261G>T p.G87= (on ENST00000427581; = p.G51= on NM_006669.6) | Silent (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
- LOXHD1 | c.1950C>T p.N650= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs371762941; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRFN1 | c.24G>A p.S8= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs1436693920; called by muse, varscan2
- NPBWR1 | c.366C>T p.S122= | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- NPHS1 | c.3555G>A p.P1185= | Silent (SNP) | VAF 121/360 reads (34%) | catalogued as rs745445890, COSV62288025; called by muse, mutect2, varscan2
- OCSTAMP | c.1611C>T p.N537= | Silent (SNP) | VAF 132/501 reads (26%) | catalogued as rs1439300382, COSV99645144; called by muse, mutect2, varscan2
- OGDH | c.354C>G p.P118= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- OR5C1 | c.702G>T p.S234= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV65456547; called by muse, mutect2, varscan2
- PAPOLB | c.474C>T p.I158= | Silent (SNP) | VAF 13/302 reads (4%) | catalogued as rs1288546191; called by muse, mutect2
- PARP3 | c.1437G>A p.P479= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs193101045; called by muse, mutect2, varscan2
- PCDHGA9 | c.628C>T p.L210= | Silent (SNP) | VAF 55/148 reads (37%) | called by muse, mutect2, varscan2
- PGLYRP3 | c.99G>C p.P33= | Silent (SNP) | VAF 85/265 reads (32%) | catalogued as COSV51949501; called by muse, mutect2, varscan2
- RFX1 | c.2481C>T p.G827= | Silent (SNP) | VAF 116/317 reads (37%) | catalogued as rs1258665094, COSV99586576; called by muse, varscan2
- RFX7 | c.1050A>T p.P350= (on ENST00000559447 / NM_001368074.1; = p.P447= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/271 reads (3%) | called by muse, mutect2
- RIMS1 | c.211A>C p.R71= | Silent (SNP) | VAF 18/201 reads (9%) | catalogued as rs980106766, COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2
- RTN4 | c.780C>T p.P260= | Silent (SNP) | VAF 51/171 reads (30%) | called by muse, varscan2
- RYR3 | c.1119T>G p.T373= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2, varscan2
- SCN3A | c.2448T>G p.P816= | Silent (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- SLC10A2 | c.411C>G p.A137= | Silent (SNP) | VAF 46/664 reads (7%) | called by muse, mutect2
- SSRP1 | c.960A>T p.A320= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- TCTN3 | c.1185T>C p.T395= | Silent (SNP) | VAF 24/198 reads (12%) | called by muse, mutect2, varscan2
- TNXB | c.9873C>T p.A3291= (on ENST00000647633; = p.A3044= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as rs544342649, COSV64473730; ClinVar: likely benign; called by muse, mutect2
- USH2A | c.12675T>C p.Y4225= | Silent (SNP) | VAF 36/406 reads (9%) | called by muse, mutect2
- ZNF701 | c.438T>C p.H146= (on ENST00000301093; = p.H80= on NM_018260.3) | Silent (SNP) | VAF 14/112 reads (13%) | called by muse, varscan2
- ZNF768 | c.453C>A p.S151= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV53225158; called by muse, mutect2, varscan2
- AC011294.1 | n.178G>A | RNA (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- AC073648.1 | n.292_293del | RNA (DEL) | VAF 68/234 reads (29%) | catalogued as rs1260271339; called by pindel, varscan2
- ATP6V0A1 | c.2421-558G>A | Intron (SNP) | VAF 12/296 reads (4%) | catalogued as rs1438396148; called by muse, mutect2
- CES2 | chr16:66935493 G>A | 5'Flank (SNP) | VAF 29/108 reads (27%) | catalogued as rs113387875; called by muse, mutect2, varscan2
- CHCHD2P9 | n.32G>A | RNA (SNP) | VAF 81/264 reads (31%) | catalogued as rs373756242; called by muse, mutect2, varscan2
- CHPF2 | c.-1328C>T | 5'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- FAIM | c.-23+1872C>G | Intron (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- GULP1 | c.843+1786G>T | Intron (SNP) | VAF 20/60 reads (33%) | called by muse, varscan2
- MIR29B2CHG | n.60G>T | RNA (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.648T>G | RNA (SNP) | VAF 25/376 reads (7%) | called by muse, mutect2
- NCAPG2 | c.3380+2821G>C | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, varscan2
- NTM | c.935-4877C>G | Intron (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- POFUT1 | c.*3124G>A | 3'UTR (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- PYHIN1 | c.579+237C>T | Intron (SNP) | VAF 53/195 reads (27%) | catalogued as rs1208953499; called by muse, mutect2, varscan2
- SLC25A22 | c.202+53G>A | Intron (SNP) | VAF 27/577 reads (5%) | catalogued as rs547622212; called by muse, mutect2
- SLC38A2 | c.116+18dup | Intron (INS) | VAF 23/138 reads (17%) | called by mutect2, pindel, varscan2
- SPATA31D5P | n.801A>T | RNA (SNP) | VAF 110/401 reads (27%) | called by muse, mutect2, varscan2
- TMEM135 | c.*2825T>A | 3'UTR (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- TMEM52 | c.129-10G>A | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- TRAV25 | c.-19G>A | 5'UTR (SNP) | VAF 28/51 reads (55%) | catalogued as rs781186889; called by muse, mutect2, varscan2
- TRIP6 | c.999+352del | Intron (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- WASHC4 | c.-40C>G | 5'UTR (SNP) | VAF 12/52 reads (23%) | catalogued as rs775449066; called by muse, mutect2
